Somatic mutation profile of tumor specimen TCGA-OR-A5KS-01A (aliquot TCGA-OR-A5KS-01A-11D-A30A-10) from TCGA case TCGA-OR-A5KS, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 72.3 years (26,404 days).
Specimen TCGA-OR-A5KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6304c7e-0b24-4179-8654-be616de0d3ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KS-10A (Blood Derived Normal), aliquot TCGA-OR-A5KS-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0986cdb-3810-47ff-8279-b9ea258f61d4

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1M1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as rs752479355; called by muse, mutect2, varscan2
- CACNA1E | c.4409G>A p.R1470H | Missense Mutation (SNP) | VAF 127/153 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV62387568; called by muse, mutect2, varscan2
- CCDC102B | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV60134300; called by muse, mutect2
- HEBP2 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV62928208; called by muse, mutect2, varscan2
- NFE2 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs139796996, COSV100380750, COSV56455524; called by muse, mutect2, varscan2
- NLRP3 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60225539; called by muse, mutect2, varscan2
- TGFBR2 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 191/330 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs1210616464; called by muse, mutect2, varscan2
- CLK1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GBP2 | c.232_238del p.I78Cfs*14 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- IRF2 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KCNQ3 | c.1838T>A p.I613N | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NIPAL4 | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NUDT9 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR5M11 | c.473A>G p.Q158R | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LRRC14B | c.918G>A p.L306= | Silent (SNP) | VAF 112/380 reads (29%) | called by muse, mutect2, varscan2
- RERG | c.591C>T p.I197= | Silent (SNP) | VAF 50/303 reads (17%) | catalogued as COSV57005534, COSV99917082; called by muse, mutect2, varscan2
- ST8SIA5 | c.831C>T p.F277= | Silent (SNP) | VAF 75/187 reads (40%) | called by muse, mutect2, varscan2
- SPTAN1 | c.6693-132G>T | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
